Gene-level copy-number profile of tumor specimen ALCH-AF3D-TTP1-A from ALCHEMIST case ALCH-AF3D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.4 years (23,143 days).
Specimen ALCH-AF3D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f3af1dc4-d7da-4670-ab43-d857362ccd16.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF3D-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/115fe15b-0af5-47c7-bdb9-7129d202dae0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 10,853; copy number 2: 47,957; copy number 3: 60; copy number 4: 2; copy number 5: 2; copy number 6: 2; copy number 12: 6; copy number 21: 2; copy number 36: 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,111,223–31,112,575, 1 gene: C6orf15.
- chr11:65,597,756–65,615,382, 1 gene (within-gene range 0–2): MAP3K11.
- chr13:24,680,408–24,712,472, 3 genes (within-gene range 0–1): ATP12A, RNY1P7, RPL26P34.
- chr13:40,789,412–40,812,460, 1 gene (within-gene range 0–1): SLC25A15.
- chr15:25,180,497–25,187,616, 5 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10.
- chr16:70,454,595–70,480,274, 1 gene: FCSK.
- chr20:3,208,868–3,239,559, 2 genes: ITPA, SLC4A11.
- chr20:4,192,932–4,195,953, 1 gene: LINC01433.
- chr20:58,995,185–59,007,254, 1 gene: CTSZ.
- chr20:63,235,883–63,240,495, 2 genes: BIRC7, MIR3196.
- chr22:41,900,944–41,901,012, 1 gene (within-gene range 0–2): MIR33A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,696,830–7,741,396, 6 genes, copy number 12: AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P.
- chr21:43,446,601–43,479,534, 2 genes, copy number 6–36 (within-gene range 4–36): LINC00319, LINC00313.
- chr21:44,107,373–44,210,114, 5 genes, copy number 5–21 (within-gene range 2–21): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 8,007. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
